Somatic mutation profile of tumor specimen TCGA-KO-8411-01A (aliquot TCGA-KO-8411-01A-11D-2310-10) from TCGA case TCGA-KO-8411, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 58.5 years (21,371 days).
Specimen TCGA-KO-8411-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f97bc5fc-4c62-42a9-b284-1b1a412558fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KO-8411-11A (Solid Tissue Normal), aliquot TCGA-KO-8411-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69ec6fe6-eb8f-49b1-b27e-f0de312f1658

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, Frame Shift Del 2, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYBPC3 | c.2905C>T p.Q969* | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as rs397515992, CM981328, COSV57025396; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BPTF | c.8683C>T p.R2895C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs1327757446, COSV58834972; called by muse, mutect2, varscan2
- GGH | c.239A>G p.E80G | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.38); catalogued as COSV99478983; called by muse, mutect2
- SLFN12 | c.555del p.F185Lfs*12 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs747319777; called by mutect2, varscan2
- SLIT1 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764611185; called by muse, mutect2, varscan2
- TOGARAM2 | c.3026C>T p.T1009I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.243); catalogued as rs761054708; called by muse, mutect2, varscan2
- WNT2B | c.583G>A p.G195S (on ENST00000369684 / NM_024494.3; = p.G176S on NM_004185.4) | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56673591; called by muse, mutect2
- ADAMTS1 | c.391G>A p.G131S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- EPS8 | c.2028_2031del p.K676Nfs*22 | Frame Shift Del (DEL) | VAF 26/102 reads (25%) | called by pindel, varscan2
- EXOC5 | c.1955A>G p.H652R | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CLEC9A | c.70C>T p.L24= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as rs868814345, COSV63351641; called by muse, mutect2, varscan2
- CTDSPL | c.399G>A p.P133= (on ENST00000273179 / NM_001008392.2; = p.P122= on NM_005808.3) | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as rs778748241; called by muse, mutect2, varscan2
- MARCHF9 | c.936C>T p.R312= | Silent (SNP) | VAF 39/93 reads (42%) | catalogued as rs760620099; called by muse, mutect2, varscan2
- ONECUT2 | c.1485G>A p.S495= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs767911692, COSV101525744; called by muse, mutect2, varscan2
- SPATA31E1 | c.1080C>T p.D360= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as rs199568188, COSV57789870; called by mutect2, varscan2
- ZNF836 | c.381T>C p.H127= | Silent (SNP) | VAF 80/197 reads (41%) | called by muse, mutect2, varscan2
- VWA1 | c.*508C>T | 3'UTR (SNP) | VAF 4/72 reads (6%) | catalogued as COSV100100776; called by muse, mutect2
